HCMI case HCM-EXPT-1171-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/36a5d5b3-1a24-46ad-aa32-45d9ec0eaf3e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1972.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 47.2 years (17,233 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Neoadjuvant; Days to treatment start: 560 days (1.5 years).
   Recorded as not given: neoadjuvant Radiation Therapy, NOS.

Biospecimens (1 sample)
- Sample HCM-EXPT-1171-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
